Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EW, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EW-01A (Primary Tumor).

ICD D-3
Carcinoma, squamous cell NOS
8070/3
Date Esophagus, middle third
path C15.4
Esophagus NOS
C15.9
JW 11/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus

PATHOLOGY REPORT:

1. "Infracarinal lymph nodes":
Number examined: 01
Number positive for neoplasia: 00
2. "Esophagus margin":
Uninvolved by invasive carcinoma
Involved by moderate dysplasia focus
3.
Specimen: Esophagus and proximal stomach
Procedure: Esophagogastrectomy
Tumor site: esophagus
Tumor size (greatest dimension): 2,5 cm
Histologic type: Squamous cell carcinoma
Histologic grade: G2 moderately differentiated
In- situ carcinoma: present
Microscopic tumor extension: tumor invades through muscularis propria into the adventitia
Lymph-vascular invasion: not identified
Perineural invasion: not identified
Mildly active chronic gastritis with extensive intestinal metaplasia (negative for H. pylori)
Margins: uninvolved by carcinoma
Regional lymph nodes:
Number examined: 13
Number positive for neoplasia: 04, with capsular involvement.

Source: NCI Genomic Data Commons file 70ae6d72-d40b-4d88-9a5b-58d15cd14daf (TCGA-VR-A8EW.0E37F896-140A-4234-A8DF-DEFE13F4BACF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).